Somatic mutation profile of tumor specimen TCGA-WE-A8JZ-06A (aliquot TCGA-WE-A8JZ-06A-11D-A372-08) from TCGA case TCGA-WE-A8JZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.9 years (26,255 days).
Specimen TCGA-WE-A8JZ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c19a29b-16f9-42d6-808b-160013b1836e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8JZ-10A (Blood Derived Normal), aliquot TCGA-WE-A8JZ-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc9fa668-1e2b-413c-b74b-140f65f62cd2

The open-access MAF lists 244 somatic variants for this specimen: 160 protein-altering or splice-affecting, 80 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 80, Nonsense Mutation 9, In Frame Del 3, RNA 3, Splice Site 2, Translation Start Site 1, Splice Region 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 88/106 reads (83%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 87/105 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AADAC | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as rs536814628, COSV51760194; called by muse, mutect2, varscan2
- AADAC | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1389735094, COSV99233157; called by muse, mutect2, varscan2
- ABCA12 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV99789230; called by muse, mutect2, varscan2
- ABCA8 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 151/299 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99285306; called by muse, mutect2, varscan2
- AFDN | c.4324G>A p.G1442S | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV100652746; called by muse, mutect2, varscan2
- ANKRD17 | c.306_329del p.G103_G110del | In Frame Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs768729766; called by muse*, mutect2
- AP1AR | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs762359168, COSV99914122; called by muse, mutect2, varscan2
- ARAP2 | c.2300G>C p.W767S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100394340; called by muse, mutect2, varscan2
- ARHGAP26 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV50829840; called by muse, mutect2, varscan2
- ARHGEF6 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 86/94 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99166409; called by muse, mutect2, varscan2
- ARSG | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101477881; called by muse, mutect2, varscan2
- ASAP3 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369316; called by muse, mutect2, varscan2
- BCO2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs200053646, COSV63063817; called by muse, mutect2, varscan2
- BIRC6 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV101428053; called by muse, mutect2, varscan2
- BRINP3 | c.427+1G>T p.X143_splice | Splice Site (SNP) | VAF 47/103 reads (46%) | catalogued as COSV100818592, COSV66541093; called by muse, mutect2, varscan2
- C12orf40 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs764478283, COSV100209837, COSV100209865; called by muse, mutect2, varscan2
- C5AR1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs770659810, COSV61892721, COSV61892949; called by muse, mutect2, varscan2
- CALCOCO1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100017230; called by muse, mutect2, varscan2
- CARF | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV100247577; called by muse, mutect2, varscan2
- CD22 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 89/112 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99323018; called by muse, mutect2, varscan2
- CD74 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 111/303 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99153602; called by muse, mutect2, varscan2
- CDH23 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs746487992, COSV99818581; called by muse, varscan2
- CDH23 | c.6437C>T p.A2146V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99819954; called by muse, mutect2, varscan2
- CDIPT | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as rs750555293, COSV54888923, COSV54889965; called by muse, mutect2, varscan2
- CEMIP2 | c.2073C>A p.F691L | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV100987295; called by muse, mutect2, varscan2
- CHCHD6 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV52066851; called by muse, mutect2, varscan2
- CIITA | c.2005C>A p.R669S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV100161644; called by muse, mutect2, varscan2
- CILP2 | c.3140C>T p.S1047F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99364496; called by muse, mutect2, varscan2
- CNGA2 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV100323528; called by muse, mutect2, varscan2
- COIL | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs1424425928, COSV99538053; called by muse, mutect2, varscan2
- COL20A1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490203; called by muse, mutect2, varscan2
- COL21A1 | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99778111; called by muse, mutect2, varscan2
- COL3A1 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58586663; called by muse, mutect2, varscan2
- CPA3 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936032; called by muse, mutect2, varscan2
- CPN1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV64942256, COSV64942384; called by muse, mutect2, varscan2
- CRNN | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 165/376 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV55120885, COSV99664307; called by muse, mutect2, varscan2
- CSMD2 | c.7589C>T p.S2530F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV53874055; called by muse, mutect2, varscan2
- CSMD3 | c.10150C>T p.L3384F (on ENST00000297405 / NM_001363185.1; = p.L3215F on NM_052900.3) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.932); catalogued as COSV52167559, COSV52225975; called by muse, mutect2, varscan2
- DCC | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.061); catalogued as rs774540293, COSV59086280, COSV59109601; called by muse, mutect2, varscan2
- DDX18 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs778782995, COSV54306284; called by muse, mutect2, varscan2
- DDX60 | c.1021A>G p.M341V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186564603, COSV101190337; called by muse, mutect2, varscan2
- DENND5A | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100064363; called by muse, mutect2, varscan2
- DNAH3 | c.6836C>T p.S2279L | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99766008; called by muse, mutect2, varscan2
- DRC1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs776709587, COSV99985204; called by muse, mutect2, varscan2
- DSG4 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV100355621; called by muse, mutect2, varscan2
- EPHA10 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1395153566, COSV100361159; called by muse, mutect2, varscan2
- EVX1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs1218556170, COSV99763907; called by muse, mutect2, varscan2
- FAM153B | c.310A>C p.T104P (on ENST00000253490; = p.T27P on NM_001265615.1) | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.063); catalogued as COSV99498848; called by muse, mutect2, varscan2
- FAM217A | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99212707; called by muse, mutect2, varscan2
- FASLG | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100390412; called by muse, mutect2, varscan2
- FGA | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV100120254; called by muse, mutect2, varscan2
- FGD5 | c.3810C>T p.I1270= | Splice Region (SNP) | VAF 27/85 reads (32%) | catalogued as rs368487979; called by muse, mutect2, varscan2
- FGF19 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594293; called by muse, mutect2, varscan2
- FNBP4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs1421571510, COSV55448335; called by muse, mutect2, varscan2
- FYB1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs746786698, COSV100685151; called by muse, mutect2, varscan2
- GALNT2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV100795623; called by muse, mutect2, varscan2
- GCLC | c.1298T>G p.V433G (on ENST00000643939; = p.V431G on NM_001498.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV99988469; called by muse, mutect2, varscan2
- GJC3 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100458396; called by muse, mutect2, varscan2
- GRIA2 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52398703; called by muse, mutect2, varscan2
- GRM6 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 55/131 reads (42%) | catalogued as COSV99179523; called by muse, mutect2, varscan2
- GUCA1B | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100027681; called by muse, mutect2, varscan2
- GUCY1A2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as COSV56486126; called by muse, mutect2, varscan2
- H2BC14 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100297537, COSV60797183; called by muse, mutect2, varscan2
- HAP1 | c.1453G>A p.E485K (on ENST00000310778 / NM_001367460.1; = p.E433K on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1555589061, COSV100169543, COSV57878586; called by mutect2, varscan2
- HAVCR1 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs1198469407, COSV100208104; called by muse, mutect2, varscan2
- HCFC1 | c.5951C>T p.A1984V | Missense Mutation (SNP) | VAF 54/57 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1557112081, COSV100128705; called by muse, mutect2, varscan2
- HPS3 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.571); catalogued as COSV99937292; called by muse, mutect2, varscan2
- HPSE | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV100264222; called by muse, mutect2, varscan2
- HSD17B4 | c.2107G>A p.G703S (on ENST00000414835 / NM_001199291.3; = p.G678S on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99819661; called by muse, mutect2, varscan2
- IL21 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.644); catalogued as COSV99144433; called by muse, mutect2, varscan2
- IMPG2 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs201089959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPPL1 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99996045; called by muse, mutect2, varscan2
- KCNMB2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64200816; called by muse, mutect2, varscan2
- KIF13A | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.255); catalogued as rs779282508, COSV99434954; called by muse, mutect2, varscan2
- KIR3DL1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.647); catalogued as rs374761764, COSV58493665; called by muse, mutect2, varscan2
- KRT28 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100137462; called by muse, mutect2, varscan2
- KRT31 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV99289536; called by muse, mutect2, varscan2
- KRTAP10-9 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs782379893, COSV100552572; called by muse, mutect2, varscan2
- KRTAP5-1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 82/162 reads (51%) | PolyPhen benign (0.042); catalogued as rs763201329, COSV66298893; called by muse, mutect2, varscan2
- KRTAP5-6 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 129/226 reads (57%) | PolyPhen probably damaging (0.995); catalogued as COSV101191723; called by muse, mutect2, varscan2
- LGR5 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs763341471, COSV57011143; called by muse, mutect2, varscan2
- LRP1B | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101254768; called by muse, mutect2, varscan2
- LRP2 | c.8197G>A p.E2733K | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); catalogued as COSV99787390; called by muse, mutect2, varscan2
- LRRC4C | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99537591; called by muse, mutect2, varscan2
- MAP3K13 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs202042288, COSV99406772; called by muse, mutect2, varscan2
- MCOLN1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs767506296, COSV99900501; called by muse, mutect2, varscan2
- MDN1 | c.4691C>T p.P1564L | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs760329454, COSV101021019; called by muse, mutect2, varscan2
- MEGF10 | c.3362C>T p.S1121F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV99174816; called by muse, mutect2
- MS4A5 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 90/105 reads (86%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100280966, COSV100281011; called by muse, mutect2, varscan2
- MUC16 | c.34031C>T p.S11344L | Missense Mutation (SNP) | VAF 111/188 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV101199166; called by muse, mutect2, varscan2
- MUC16 | c.23387C>A p.P7796Q | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV101199167; called by muse, mutect2, varscan2
- MYO5B | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53212058, COSV53212241; called by muse, mutect2, varscan2
- NCAM2 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 53/98 reads (54%) | catalogued as COSV53054290, COSV99522340; called by muse, mutect2, varscan2
- NEUROD4 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754528345, COSV99669698; called by muse, mutect2, varscan2
- NLGN4X | c.1493G>C p.G498A | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320884, COSV99322774; called by muse, mutect2, varscan2
- NME8 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV52250540; called by muse, mutect2, varscan2
- NMUR2 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54916892, COSV99676759; called by muse, mutect2, varscan2
- NPNT | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV99974916; called by muse, mutect2, varscan2
- NRG1 | c.998C>T p.S333F (on ENST00000405005 / NM_013964.5; = p.S338F on NM_013956.5) | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99828037; called by muse, mutect2, varscan2
- NRXN3 | c.2221G>A p.G741R (on ENST00000335750 / NM_001330195.2; = p.G368R on NM_004796.6) | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59810961; called by muse, mutect2, varscan2
- NUP210 | c.4766G>A p.R1589K | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99595901; called by muse, mutect2, varscan2
- NXPE1 | c.967G>A p.G323R (on ENST00000424269; = p.G181R on NM_152315.5) | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV99320160; called by muse, mutect2, varscan2
- OVGP1 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as COSV100868068; called by muse, mutect2, varscan2
- P3H1 | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99354995; called by muse, mutect2, varscan2
- P3H3 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99301038; called by muse, mutect2, varscan2
- PATJ | c.3365G>A p.G1122E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866800533, COSV100333672; called by muse, mutect2, varscan2
- PCDH15 | c.5411G>A p.G1804D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.034); catalogued as COSV57263738; called by muse, mutect2, varscan2
- PCDHA6 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.057); catalogued as COSV100971342; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, mutect2, varscan2
- PCDHGA11 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54023583; called by muse, mutect2, varscan2
- PCDHGA7 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.042); catalogued as COSV99534452; called by muse, mutect2, varscan2
- PDE6C | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs777483878, COSV101008637; called by muse, mutect2, varscan2
- PKHD1L1 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV101005810; called by muse, mutect2, varscan2
- PNMA5 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.736); catalogued as COSV100721615; called by muse, mutect2, varscan2
- POGZ | c.4156C>T p.Q1386* | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | catalogued as COSV99304909; called by muse, mutect2, varscan2
- PPFIA4 | c.1989G>T p.M663I (on ENST00000447715; = p.M664I on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99690416; called by muse, mutect2, varscan2
- PRAMEF12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255032935, COSV100743135; called by muse, mutect2, varscan2
- PRICKLE2 | c.778G>A p.A260T (on ENST00000295902; = p.A204T on NM_198859.4) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55772530, COSV99896935; called by muse, mutect2, varscan2
- PRRC2B | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs766520902, COSV100621635; called by muse, mutect2, varscan2
- RBM8A | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV57162385; called by muse, mutect2, varscan2
- RBPMS | c.278C>G p.T93R | Missense Mutation (SNP) | VAF 102/166 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99823777; called by muse, mutect2, varscan2
- RNPS1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as rs1354981454, COSV57046801; called by muse, mutect2
- ROBO2 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.089); catalogued as COSV100165451; called by muse, mutect2, varscan2
- RP1 | c.6409G>A p.E2137K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV55122067; called by muse, mutect2, varscan2
- RRM1 | c.1905+1G>T p.X635_splice | Splice Site (SNP) | VAF 80/144 reads (56%) | catalogued as COSV100331264; called by muse, mutect2, varscan2
- SCD5 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 71/124 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV99907852; called by muse, mutect2, varscan2
- SCN9A | c.2776G>A p.G926R (on ENST00000303354; = p.G915R on NM_002977.3) | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312100; called by muse, mutect2, varscan2
- SERPINA7 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 206/239 reads (86%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV100568255; called by muse, mutect2, varscan2
- SLC34A1 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100183855, COSV60999569; called by muse, mutect2, varscan2
- SLPI | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 159/246 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100619751; called by muse, mutect2, varscan2
- SMG6 | c.3130C>T p.P1044S | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53976820; called by muse, mutect2, varscan2
- SNRPD3 | c.270C>A p.N90K | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1173891655, COSV99307474, COSV99307635; called by muse, mutect2, varscan2
- SPTBN5 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs773220094, COSV100311054; called by muse, varscan2
- STARD6 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.396); catalogued as rs1361780231, COSV100323387; called by muse, mutect2, varscan2
- TAS2R16 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99972214; called by muse, mutect2, varscan2
- TBC1D23 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV100792512; called by muse, mutect2, varscan2
- TDRD5 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675867; called by muse, mutect2, varscan2
- THBS4 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV63470739; called by muse, mutect2, varscan2
- TRANK1 | c.3701C>T p.S1234F | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100082231; called by muse, mutect2, varscan2
- TWNK | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99272188; called by muse, mutect2, varscan2
- UGGT2 | c.2943G>A p.M981I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV100948565; called by muse, mutect2, varscan2
- UNC5A | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV99458168; called by muse, mutect2, varscan2
- USP7 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100784109; called by muse, mutect2, varscan2
- VPS13A | c.7082G>A p.R2361K | Missense Mutation (SNP) | VAF 68/82 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1372664900, COSV100652444; called by muse, mutect2, varscan2
- WBP4 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101069240, COSV101069306; called by muse, mutect2, varscan2
- XIRP2 | c.7858G>A p.D2620N (on ENST00000628543; = p.D2795N on NM_152381.6) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747530280, COSV99740792; called by muse, mutect2, varscan2
- ZBED9 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101509179; called by muse, mutect2, varscan2
- ZBTB7C | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776489177, COSV59688571; called by muse, mutect2, varscan2
- ZKSCAN3 | c.751T>G p.S251A | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99356851; called by muse, mutect2, varscan2
- ZNF229 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 93/132 reads (70%) | catalogued as COSV99350255; called by muse, mutect2, varscan2
- ZNF286A | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV101224748, COSV67845174; called by muse, mutect2, varscan2
- ZNF560 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as COSV100038401; called by muse, mutect2, varscan2
- ZNF823 | c.1244C>T p.P415L (on ENST00000341191 / NM_001297610.2; = p.P371L on NM_017507.2) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100362453; called by muse, mutect2, varscan2
- ZSCAN10 | c.1723G>A p.G575S (on ENST00000252463; = p.G630S on NM_032805.3) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1334406893, COSV99373923; called by muse, mutect2, varscan2
- DUS1L | c.281_286del p.L94_A95del | In Frame Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- DUSP6 | c.981dup p.S328Ifs*6 | Frame Shift Ins (INS) | VAF 60/129 reads (47%) | called by mutect2, pindel, varscan2
- KIAA1328 | c.910_924del p.Q304_H308del | In Frame Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- WASHC2C | c.3431C>T p.S1144F (on ENST00000336378; = p.S1123F on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ABCC9 | c.1542C>T p.F514= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV53964929; called by muse, mutect2, varscan2
- ADCY8 | c.633C>T p.L211= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV99651493; called by muse, mutect2, varscan2
- AKR1C8P | c.147C>T p.F49= | Silent (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- AOAH | c.744C>T p.F248= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV51736413, COSV99332448; called by muse, mutect2, varscan2
- ASAP3 | c.1803C>G p.S601= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100369315; called by muse, mutect2, varscan2
- ASCC2 | c.780G>A p.L260= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100316135; called by muse, mutect2, varscan2
- ATP5F1A | c.771C>T p.A257= | Silent (SNP) | VAF 113/247 reads (46%) | catalogued as COSV56361984; called by muse, mutect2, varscan2
- C1orf141 | c.171C>T p.S57= | Silent (SNP) | VAF 85/197 reads (43%) | catalogued as rs769884072, COSV63993429; called by muse, mutect2, varscan2
- CASP5 | c.420C>A p.I140= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV52828811; called by muse, mutect2, varscan2
- CASR | c.1002G>A p.L334= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV99948719; called by muse, mutect2, varscan2
- CCBE1 | c.1035C>T p.I345= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV101232802; called by muse, varscan2
- CDC16 | c.1785C>T p.S595= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99372828; called by muse, mutect2, varscan2
- CDC42BPB | c.4665G>A p.R1555= | Silent (SNP) | VAF 97/121 reads (80%) | catalogued as rs769470267, COSV100775328; called by muse, mutect2, varscan2
- CDH7 | c.765C>T p.V255= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV100541873; called by muse, mutect2, varscan2
- CDK5 | c.348C>T p.F116= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV99876774; called by muse, mutect2, varscan2
- CFAP46 | c.247C>T p.L83= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV63954744; called by muse, mutect2, varscan2
- CILP2 | c.3141C>T p.S1047= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV52275992; called by muse, mutect2, varscan2
- CPSF7 | c.618G>A p.E206= (on ENST00000394888 / NM_001136040.4; = p.E249= on NM_024811.4) | Silent (SNP) | VAF 64/78 reads (82%) | catalogued as COSV100467143; called by muse, mutect2, varscan2
- CRACD | c.2310G>T p.G770= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV99948928; called by muse, mutect2, varscan2
- CUX2 | c.3231G>A p.L1077= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1446644447, COSV99919196; called by muse, mutect2, varscan2
- CXCR1 | c.51C>T p.F17= | Silent (SNP) | VAF 99/258 reads (38%) | catalogued as rs1490609886, COSV99826275; called by muse, mutect2, varscan2
- DLL4 | c.1770G>A p.Q590= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as COSV99989716; called by muse, mutect2, varscan2
- DRC1 | c.741C>T p.A247= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV56532479; called by muse, mutect2, varscan2
- FBXL20 | c.1176C>T p.I392= | Silent (SNP) | VAF 120/237 reads (51%) | catalogued as COSV99233932; called by muse, mutect2, varscan2
- FCRL4 | c.1338G>A p.E446= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs1188678700, COSV99619513; called by muse, mutect2, varscan2
- FLG | c.2334C>T p.S778= | Silent (SNP) | VAF 173/442 reads (39%) | catalogued as rs771168723, COSV64244551; called by muse, mutect2, varscan2
- GAB1 | c.1995G>A p.Q665= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs771500396, COSV99528141; called by muse, mutect2, varscan2
- GABRA1 | c.741G>A p.K247= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV99195787; called by muse, mutect2, varscan2
- GK2 | c.1140C>T p.L380= | Silent (SNP) | VAF 77/139 reads (55%) | catalogued as rs866542206, COSV100725907; called by muse, mutect2, varscan2
- GNPAT | c.1698A>G p.L566= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV100791591; called by muse, mutect2, varscan2
- GPR156 | c.1980G>A p.R660= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV100251259; called by muse, mutect2, varscan2
- GRIK4 | c.1002C>T p.S334= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as COSV101483574; called by muse, mutect2, varscan2
- GRM2 | c.1035C>T p.F345= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99622636; called by muse, mutect2, varscan2
- HAP1 | c.1452G>A p.Q484= (on ENST00000310778 / NM_001367460.1; = p.Q432= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1457016255, COSV100169546; called by mutect2, varscan2
- HAUS1 | c.276C>T p.S92= | Silent (SNP) | VAF 81/189 reads (43%) | catalogued as COSV99959407; called by muse, mutect2, varscan2
- HECW1 | c.3849C>T p.T1283= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV101223150; called by muse, mutect2, varscan2
- HFM1 | c.1611G>A p.R537= | Silent (SNP) | VAF 44/50 reads (88%) | catalogued as rs1312059105, COSV99645735; called by muse, mutect2, varscan2
- ITPR2 | c.1095C>T p.S365= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV101189909; called by muse, mutect2, varscan2
- JMY | c.2521C>T p.L841= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs560761134, COSV101267975; called by muse, mutect2, varscan2
- KCNK10 | c.336C>T p.F112= | Silent (SNP) | VAF 28/32 reads (88%) | catalogued as COSV56652545; called by muse, mutect2, varscan2
- KCNK6 | c.808C>T p.L270= | Silent (SNP) | VAF 88/118 reads (75%) | catalogued as COSV99649318; called by muse, mutect2, varscan2
- KIAA0319 | c.687C>T p.L229= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs776084304, COSV100985397, COSV65496804; called by muse, mutect2, varscan2
- LRRN1 | c.1104C>T p.I368= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV60016320; called by muse, mutect2, varscan2
- MYO3A | c.981G>A p.G327= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs1324556520, COSV99779021; called by muse, mutect2, varscan2
- MYPN | c.1710G>A p.V570= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs866158637, COSV100589768; called by muse, mutect2, varscan2
- NALCN | c.3966G>A p.K1322= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV51930904; called by muse, mutect2, varscan2
- NMUR2 | c.399C>T p.S133= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV99676757; called by muse, mutect2, varscan2
- NPL | c.945C>T p.N315= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as COSV99277410; called by muse, mutect2, varscan2
- NUGGC | c.1962G>A p.R654= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs771242077, COSV100429094; called by muse, varscan2
- OR10AG1 | c.447G>A p.G149= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as COSV56632022; called by muse, mutect2, varscan2
- OR1C1 | c.642C>T p.I214= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs1434099462, COSV101376207; called by muse, mutect2, varscan2
- OR1J1 | c.339C>T p.F113= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs771008540, COSV52237221; called by muse, mutect2, varscan2
- OR6T1 | c.966G>A p.R322= | Silent (SNP) | VAF 57/67 reads (85%) | catalogued as rs866729485, COSV58309565; called by muse, mutect2, varscan2
- OR6X1 | c.663C>T p.S221= | Silent (SNP) | VAF 47/62 reads (76%) | catalogued as rs759293628, COSV100020490; called by muse, mutect2, varscan2
- OTUD7A | c.1842G>A p.P614= (on ENST00000307050 / NM_001382637.1; = p.P607= on NM_130901.3) | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1241227024, COSV100191908; called by muse, mutect2, varscan2
- PCDH10 | c.3108G>A p.R1036= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as rs966548291, COSV52091539; called by muse, mutect2, varscan2
- PCDHB7 | c.2100C>T p.L700= | Silent (SNP) | VAF 81/294 reads (28%) | catalogued as COSV99176512; called by muse, mutect2, varscan2
- PITPNM2 | c.519C>T p.S173= | Silent (SNP) | VAF 107/194 reads (55%) | catalogued as rs755275047, COSV99758561; called by muse, mutect2, varscan2
- POGZ | c.4155C>T p.H1385= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV99304912; called by muse, mutect2, varscan2
- POR | c.1458C>A p.G486= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs782616971, COSV100115529; called by muse, mutect2, varscan2
- RPRD2 | c.3654C>T p.V1218= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs764828135, COSV64824181; called by muse, mutect2, varscan2
- RPS23 | c.33G>A p.R11= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV99688425; called by muse, mutect2, varscan2
- SBF1 | c.411G>A p.S137= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs769350649, COSV62370334; called by muse, mutect2, varscan2
- SLC10A4 | c.603C>A p.T201= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV99906815; called by muse, mutect2, varscan2
- SLC22A10 | c.1137C>T p.F379= | Silent (SNP) | VAF 66/87 reads (76%) | catalogued as rs564171817, COSV60419818; called by muse, mutect2, varscan2
- SLC35F3 | c.1254C>T p.S418= (on ENST00000366617 / NM_001300845.1; = p.S487= on NM_173508.4) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs754124985, COSV100784762; ClinVar: likely benign; called by muse, mutect2
- SSU72 | c.267G>A p.K89= | Silent (SNP) | VAF 123/259 reads (47%) | catalogued as COSV52218697; called by muse, mutect2, varscan2
- TACC2 | c.7839C>T p.S2613= (on ENST00000334433; = p.S691= on NM_006997.4) | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV99586842; called by muse, mutect2, varscan2
- TBC1D9 | c.2331C>T p.S777= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV101464306; called by muse, mutect2, varscan2
- TECTA | c.534C>T p.F178= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as COSV99879270; called by muse, mutect2, varscan2
- TGM6 | c.462G>A p.Q154= | Silent (SNP) | VAF 32/42 reads (76%) | catalogued as COSV99171738; called by muse, mutect2, varscan2
- TLN2 | c.6097C>T p.L2033= | Silent (SNP) | VAF 46/57 reads (81%) | catalogued as rs1373459447, COSV100168524; called by muse, mutect2, varscan2
- TOX2 | c.177C>T p.L59= (on ENST00000358131 / NM_001098798.2; = p.L8= on NM_032883.3) | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV100363654; called by muse, mutect2, varscan2
- USP7 | c.1329G>A p.K443= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV100784112; called by muse, mutect2, varscan2
- VWC2 | c.900C>T p.C300= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100514020; called by muse, mutect2, varscan2
- ZBTB39 | c.2103C>T p.I701= | Silent (SNP) | VAF 57/94 reads (61%) | catalogued as rs1467039314, COSV100267980, COSV55630721; called by muse, mutect2, varscan2
- ZFHX4 | c.4707G>A p.L1569= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV99260298; called by muse, mutect2, varscan2
- ZMIZ2 | c.2737C>T p.L913= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99536725; called by muse, mutect2, varscan2
- ZNF440 | c.1680C>T p.Y560= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs766528860, COSV58371015; called by muse, mutect2
- ZNF559 | c.720C>T p.F240= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as rs1413236061, COSV100416413, COSV100416481; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.770C>T | RNA (SNP) | VAF 65/92 reads (71%) | called by muse, mutect2, varscan2
- SLC17A2 | c.*145G>A | 3'UTR (SNP) | VAF 29/139 reads (21%) | catalogued as rs142926590, COSV55351962; called by muse, mutect2, varscan2
- SPATA8 | n.273G>A | RNA (SNP) | VAF 27/30 reads (90%) | catalogued as rs267604397, COSV60703913; called by muse, mutect2, varscan2
- XIST | n.9597G>A | RNA (SNP) | VAF 26/29 reads (90%) | catalogued as rs959599803; called by muse, mutect2, varscan2
